Somatic mutation profile of tumor specimen 0DVPON from CCDI case PBCLUA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pineoblastoma; Tissue or organ of origin: Pineal gland; Age at diagnosis: 6.1 years (2,211 days).
Specimen 0DVPON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da235a3c-d5d5-4414-b2d4-52102f26c051.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1fc93a8-8649-4dee-8144-823c13b66a10

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, Silent 2, 3'UTR 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC146 | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 116/1413 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs757394526, COSV53551808; called by muse, mutect2
- CEP170B | c.1541C>T p.P514L (on ENST00000453495; = p.P443L on NM_015005.3) | Missense Mutation (SNP) | VAF 371/831 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs752496892; called by muse, mutect2, varscan2
- CLGN | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 80/1284 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV57773126; called by muse, mutect2
- EXTL1 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 30/702 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs931336284; called by muse, mutect2
- GALNT15 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 86/1096 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs375198104; called by muse, mutect2
- GDAP1L1 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 207/675 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs370507208; called by muse, mutect2, varscan2
- LNX1 | c.677G>A p.R226Q (on ENST00000263925 / NM_001126328.3; = p.R130Q on NM_032622.2) | Missense Mutation (SNP) | VAF 424/1201 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs764651628; called by muse, mutect2, varscan2
- PRSS37 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 70/1336 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV63339874; called by muse, mutect2
- ZC3H18 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 132/1410 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs769959442; called by muse, mutect2
- CAMK4 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 81/780 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL18A1 | c.2933C>T p.A978V (on ENST00000359759 / NM_130444.3; = p.A743V on NM_030582.4) | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.059); called by muse, mutect2
- MMP25 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 19/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SLC16A7 | c.1015A>T p.S339C | Missense Mutation (SNP) | VAF 368/990 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- STIL | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 347/848 reads (41%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZMYM3 | c.3676G>T p.E1226* | Nonsense Mutation (SNP) | VAF 21/392 reads (5%) | called by muse, mutect2
- ZNF716 | c.583T>C p.C195R | Missense Mutation (SNP) | VAF 36/1292 reads (3%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, mutect2
- OBSCN | c.14706C>T p.H4902= | Silent (SNP) | VAF 109/370 reads (29%) | called by muse, mutect2, varscan2
- RAB3D | c.12T>A p.A4= | Silent (SNP) | VAF 185/489 reads (38%) | called by muse, mutect2, varscan2
- CIT | c.3715-717G>A | Intron (SNP) | VAF 66/762 reads (9%) | called by muse, mutect2
- CWH43 | c.803-51C>T | Intron (SNP) | VAF 95/228 reads (42%) | called by muse, mutect2, varscan2
- INTS8 | c.2414+33T>C | Intron (SNP) | VAF 106/2696 reads (4%) | called by muse, mutect2
- PANX1 | c.*39G>A | 3'UTR (SNP) | VAF 173/526 reads (33%) | catalogued as rs768678919; called by muse, mutect2, varscan2
- SIGLEC9 | c.-33T>A | 5'UTR (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
